Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0CL, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0CL-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: Specimen #:
FMP/SSN:
DOB/Age/Sex: (Age: F Race: BLACK Taken:
Location: Received:
Physician(s): Reported:

SPECIMEN: RIGHT BREAST AND AXILLARY CONTENT

100-0-3
Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9 1/24/11 pr

FINAL DIAGNOSIS:

BREAST, RIGHT; MASTECTOMY WITH AXILLARY LYMPH NODES:

TUMOR TYPE: INFILTRATING DUCTAL CARCINOMA

NOTTINGHAM GRADE: POORLY DIFFERENTIATED

NOTTINGHAM SCORE: 9 OF 9

(Tubules= 3, Nuclei= 3, Mitoses= 3)

TUMOR SIZE (GREATEST DIMENSION): 5.6 CM (MEASURED GROSSLY)

TUMOR NECROSIS: PRESENT IN INFILTRATING COMPONENT.

MICROCALCIFICATIONS: PRESENT IN TUMOR.

VENOUS / LYMPHATIC INVASION: PRESENT (EXTENSIVE)

MARGINS: DEEP MARGIN IS INVOLVED BY INFILTRATING TUMOR.

-DISTANCE OF TUMOR FROM NEAREST MARGIN IS 0 CM, FROM DEEP MARGIN.

INTRADUCTAL COMPONENT: PRESENT

LYMPH NODES: 9 OF 12 POSITIVE FOR TUMOR; LARGEST METASTATIC FOCUS IS 1.5 CM

ESTROGEN RECEPTORS: POSITIVE (20%) (PERFORMED ON

PROGESTERONE RECEPTORS: NEGATIVE (less than 5%) (PERFORMED ON

HER 2 NEU by IHC: NEGATIVE (1%) (PERFORMED ON

PATHOLOGIC STAGE: pT3 N2a M# (AJCC Stage IIIA)

** Report Electronically Signed Out **

CLINICAL DIAGNOSIS AND HISTORY:

year old female with right breast cancer

PRE-OPERATIVE DIAGNOSIS:

Right breast cancer

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION:

A. Received fresh and consists of 553 gram right mastectomy specimen with axillary tail. Specimen measures 22 cm medial to lateral, 18 cm superior to inferior, 3 cm anterior to posterior. Superficial skin ellipse is darkly pigmented and measures 18 x 7 cm. Centrally everted nipple is surrounded by nodular areolar. No scar or discharge is noted. Deep resection margin is inked black. Specimen serially sectioned to reveal 5.6 x 3.5 x 1.5 cm poorly circumscribed firm gritty mass within the lateral outer quadrant. Located 5 cm from this mass at the mid inner aspect at 3:00 there is a second similar appearing mass measuring 2.5 x 2.5 x 1.0 cm. The surrounding tissue shows marked hemorrhage consistent with previous biopsy located within lateral inner quadrant is a 1 x 0.8 x 0.5 cm similar mass located 5 cm from 3:00 mass. Also within lateral inner quadrant is a 1.5 x 0.7 x 0.5 cm similar mass abutting deep margin. Remainder of breast parenchyma is composed of 40% dense slightly nodular fibrous tissue. Fatty tissue is unremarkable.

Attached axillary tail measures 8 x 5 x 1 cm and contains twelve lymph nodes ranging from 0.7 to 2 cm in greatest dimension. Upon sectioning the cut surfaces are predominantly firm, pink white and appear involved by lesion. Cassette key:

- A1: skin
- A2: nipple
- A3: LOQ mass inferior portion
- A4: LOQ mass superior portion
- A5: mid inner quadrant 3:00 mas
- A6: LIQ mass
- A7: LIQ mass at margin
- A8: LOQ
- A9: LIQ
- A10: UIQ
- A11: UOQ
- A12: largest lymph node, low axillary
- A13: low axillary lymph node
- A14: low axillary lymph node
- A15: high axillary lymph node
- A15-A18: two lymph nodes bisected in each cassette
- A19-A20: one bisected lymph node in each cassette

Matched sections of A1-A6 and A8-A15 placed in for CBCP protocol.

HistAA Discrepancy		☒

Source: NCI Genomic Data Commons file 93666ae8-c8ef-4193-9413-9e57c13925bd (TCGA-A2-A0CL.17950062-E052-4FC2-A437-A17669B4DD01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).